Gene-level copy-number profile of tumor specimen CDDP-ABM9-TTP1-A from CDDP_EAGLE case CDDP-ABM9, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 52 years.
Specimen CDDP-ABM9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b544d787-1808-4dd4-b9bd-d2995fc46c2b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ABM9-NC1-A (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,740 have no estimate.
https://portal.gdc.cancer.gov/files/6c4e3e29-aceb-4685-9411-f9f2b9b1be9b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 184; copy number 1: 1,409; copy number 2: 2,895; copy number 3: 9,480; copy number 4: 20,584; copy number 5: 5,860; copy number 6: 12,170; copy number 7: 1,622; copy number 8: 3,954; copy number 9: 293; copy number 10: 419; copy number 12: 13.

Homozygous deletions (total copy number 0; autosomes only): 184 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:64,091–8,244,865, 184 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 725 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:36,740,775–39,229,475, 49 genes, copy number 9: CPNE5, Z85996.2, PPIL1, C6orf89, AL122034.1, PI16, MTCH1, FGD2, COX6A1P2, RPL12P2, PIM1, TMEM217, AL353579.1, TBC1D22B, AL096712.1, AL096712.2, RNF8, RN7SL273P, CMTR1, CCDC167, LINC02520, AL353597.2, AL353597.1, MIR4462, AL353597.3, MDGA1, AL121574.1, ZFAND3, RN7SL285P, RNVU1-33, AL589655.1, BTBD9, AL033518.1, BTBD9-AS1, Y_RNA, AL079341.1, GLO1, AL391415.1, DNAH8, RN7SL465P, AL035555.2, AL035555.1, DNAH8-AS1, AL034345.1, AL035690.1, GLP1R, SAYSD1, ANKRD18EP, KCNK5.
- chr7:37,032–11,520,175, 224 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr7:11,406,955–11,414,078, 1 gene, copy number 9 (within-gene range 8–9): AC004160.2.
- chr7:25,948,657–31,708,455, 143 genes, copy number 10 (broad region; genes not listed).
- chr7:63,011,463–63,456,687, 32 genes, copy number 9–12: RNU6-417P, AC069285.2, AC069285.3, ZNF90P3, SAPCD2P4, SEPTIN14P1, AC069285.1, AC092001.1, PHKG1P1, AC006455.8, SEPTIN7P4, AC006455.7, ZNF733P, AC006455.1, ARAFP3, AC006455.6, AC006455.5, AC006455.2, AC006455.3, AC006455.4, VN1R31P, VN1R32P, AC073188.3, AC073188.4, AC073188.2, AC073188.1, AC073188.5, AC073188.6, SLC25A1P2, VN1R33P, ARAFP2, ZNF734P.
- chr8:40,114,651–40,520,158, 6 genes, copy number 10: LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1, AC010857.1.
- chr22:15,282,557–21,044,117, 270 genes, copy number 10 (within-gene range 4–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 959. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
